Gene-level copy-number profile of tumor specimen HCM-CSHL-0802-C67-01A from HCMI case HCM-CSHL-0802-C67, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; Tumor grade: G3.
Specimen HCM-CSHL-0802-C67-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file b8a5eca7-f33d-4c72-afe4-35d0bfe1763c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0802-C67-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/86face0e-0bc9-4585-aa8d-e75833e13bbd

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 517; copy number 2: 41,091; copy number 3: 10,331; copy number 4: 4,549; copy number 5: 1,510; copy number 6: 648; copy number 7: 94; copy number 8: 1; copy number 10: 24; copy number 12: 2; copy number 16: 104.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:196,774,813–196,795,407, 1 gene: CFHR3.
- chr4:39,399,149–39,399,248, 1 gene: RNU6-887P.
- chr4:39,411,910–39,411,974, 1 gene (within-gene range 0–2): MIR5591.
- chr6:58,386,799–60,546,660, 2 genes: AL603755.1, AC244258.1.
- chr10:133,420,666–133,431,318, 2 genes (within-gene range 0–3): SPRN, OR6L2P.
- chr11:48,880,111–48,908,946, 4 genes: AC027369.6, AC027369.3, AC027369.4, AC027369.5.
- chr11:50,307,681–55,271,114, 15 genes: AC024405.2, AC024405.1, OR4C50P, OR4C46, OR4C7P, OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P, OR4A5, OR4A6P, TRIM48, AP005597.4.
- chr11:94,377,316–94,401,419, 1 gene: GPR83.
- chr21:8,996,496–9,129,752, 6 genes: CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2.
- chr21:10,640,028–10,649,835, 2 genes: AF254982.1, IGHV1OR21-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,383 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:29,236,516–29,709,547, 4 genes, copy number 5: PTPRU, LINC01756, AL671862.1, AC092265.1.
- chr1:83,575,776–83,861,023, 2 genes, copy number 5: LINC01725, AL035706.1.
- chr3:72,888,046–75,670,185, 51 genes, copy number 6–7: GXYLT2, Metazoa_SRP, FTH1P23, PPP4R2, RNU7-19P, EBLN2, RNU6-557P, RNU2-64P, CCDC75P1, RNU6-1270P, PDZRN3, RNU7-119P, PDZRN3-AS1, AC117489.1, AC108725.1, LINC02005, Metazoa_SRP, LINC02047, AC016930.1, AKR1B1P2, CNTN3, NIPA2P2, RN7SL294P, MIR4444-2, AC117481.1, HNRNPA3P6, MYLKP1, OR7E66P, OR7E22P, OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1, OR7E121P, UNC93B3, RPL23AP49, AC108724.2, CLUHP10, MIR1324, AGGF1P3, RARRES2P1, FRG2C, DUX4L26.
- chr5:58,198–45,895,970, 679 genes, copy number 6–7 (broad region; genes not listed).
- chr7:55,436,056–55,572,988, 1 gene, copy number 6: VOPP1.
- chr12:45,014,672–47,079,959, 33 genes, copy number 6–10 (within-gene range 1–10): DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1, SLC38A4, AC079906.1, AMIGO2.
- chr13:18,467,172–20,232,365, 67 genes, copy number 5 (broad region; genes not listed).
- chr13:21,298,139–41,961,120, 358 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr13:52,652,709–114,337,626, 639 genes, copy number 5 (broad region; genes not listed).
- chr15:20,657,638–20,688,408, 1 gene, copy number 8 (within-gene range 2–8): NBEAP1.
- chr15:20,890,206–20,935,658, 4 genes, copy number 6–12: AC012414.5, AC037471.2, ZNF519P2, NF1P1.
- chr17:31,851,871–32,997,877, 52 genes, copy number 5: COPRS, UTP6, AC004253.1, SUZ12, RNA5SP437, AC090616.3, LRRC37B, AC090616.4, SH3GL1P1, AC090616.6, AC090616.2, AC090616.5, AC090616.1, WDR45BP1, AC116407.2, AC116407.1, RHOT1, ARGFXP2, AC116407.4, AC116407.3, UBL5P2, RHBDL3, AC026620.1, AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207, AC005899.6, AC005899.7, AC005899.5, AC005899.8, AC005899.1, AC005899.2, PSMD11, Y_RNA, CDK5R1, MYO1D, AC079336.5, AC079336.7, AC079336.2, AC079336.1, AC079336.6, AC079336.4, AC079336.3, AC025211.1, Y_RNA, AC084809.1, AC084809.2, TMEM98, SPACA3.
- chr17:36,225,246–36,334,759, 7 genes, copy number 5: AC243829.5, AC243829.3, AC243829.6, TBC1D3I, AC233699.1, Y_RNA, TBC1D3G.
- chr17:36,486,629–40,100,589, 137 genes, copy number 5–16 (broad region; genes not listed).
- chr20:87,250–17,682,295, 321 genes, copy number 5 (broad region; genes not listed).
- chr21:7,744,962–8,454,792, 26 genes, copy number 5: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr22:30,182,818–30,207,195, 1 gene, copy number 5: AC002378.1.

Autosomal genes at a single copy (total copy number 1): 517. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
